TCGA case TCGA-HB-A3L4 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/520088b0-ffc0-4ecd-b1ed-2339811d7ad2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 46 years; Vital status: Dead; Days to death: 1,061 days (2.9 years).

Diagnoses (5)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 46.7 years (17,044 days); Year of diagnosis: 2009; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS / Uterus; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 18.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 8; Tumor length measurement: 18; Tumor width measurement: 14.
   Pathology details: Measurement type: Radiologic; Tumor burden: 14.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 9.6; Tumor length measurement: 14; Tumor width measurement: 12.4.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 47.6 years (17,370 days); Days to diagnosis: 326 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.1.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 1.2.
   Pathology details: Measurement type: Radiologic; Tumor burden: 2.7.
   Pathology details: Measurement type: Pathologic; Tumor burden: 3.1.
   Pathology details: Measurement type: Pathologic; Tumor burden: 3.1.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.6.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 1.9.
   Pathology details: Measurement type: Radiologic; Tumor burden: 2.7.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 47.8 years (17,468 days); Days to diagnosis: 424 days (1.2 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 48.0 years (17,533 days); Days to diagnosis: 489 days (1.3 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 9; Tumor width measurement: 7.1.
   Pathology details: Measurement type: Radiologic; Tumor burden: 13.9.
   Pathology details: Measurement type: Pathologic; Tumor burden: 14.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6; Tumor length measurement: 8.5; Tumor width measurement: 7.
   Pathology details: Measurement type: Pathologic; Tumor burden: 14.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 4.9; Tumor width measurement: 4.3.
   Pathology details: Measurement type: Radiologic; Tumor burden: 13.9.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.5; Tumor length measurement: 5.5; Tumor width measurement: 4.
5. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 48.5 years (17,727 days); Days to diagnosis: 683 days (1.9 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 424 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 424 days (1.2 years).
- Day 489 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 489 days (1.3 years); Discontiguous lesion count: 2.
- Day 683 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 683 days (1.9 years).
- Days to follow up: 861 days (2.4 years); Disease response: With Tumor.
- Days to follow up: 1,061 days (2.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 90.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HB-A3L4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 190 mg.
  Slide TCGA-HB-A3L4-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HB-A3L4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HB-A3L4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Disease multifocal indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus; Submitted tumor site: Gynecological - Cervix.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 8.
- Follow-up form 1: Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 3: Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 5: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Regimen number: 1; Prescribed dose: 100; Pharmaceutical treatment dose units: mg/m2; Pharma adjuvant cycles count: 8; Days from index date to pharmaceutical treatment started: 32; Days from index date to pharmaceutical treatment ended: 216; Pharmaceutical therapy drug name: Taxotere; Therapy regimen: Adjuvant; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Prescribed dose: 900; Pharmaceutical treatment dose units: mg/m2; Pharma adjuvant cycles count: 8; Days from index date to pharmaceutical treatment started: 32; Days from index date to pharmaceutical treatment ended: 216; Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Adjuvant; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 3: Regimen number: 2; Prescribed dose: 50; Pharmaceutical treatment dose units: mg/m2; Pharma adjuvant cycles count: 3; Days from index date to pharmaceutical treatment started: 431; Days from index date to pharmaceutical treatment ended: 473; Pharmaceutical therapy drug name: Adriamycin; Therapy regimen: Progression; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 4: Regimen number: 4; Prescribed dose: 2.8; Pharmaceutical treatment dose units: g/day; Pharma adjuvant cycles count: 11; Days from index date to pharmaceutical treatment started: 734; Days from index date to pharmaceutical treatment ended: 945; Pharmaceutical therapy drug name: Ifosfamide; Therapy regimen: Progression; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 5: Regimen number: 3; Prescribed dose: 2.5; Pharmaceutical treatment dose units: mg/day; Days from index date to pharmaceutical treatment started: 582; Pharmaceutical therapy drug name: Letrozole; Therapy regimen: Progression; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment 5, Therapy types: Pharmaceutical therapy type: Hormone Therapy.
- Drug treatment 5, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,061 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,061 days; disease-free interval: event (new tumor event after initially disease-free), 326 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 326 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HB-A3L4-01A-11D-A21P-01): tumor purity 0.98, ploidy 1.85, whole-genome doublings 0.
